Somatic mutation profile of tumor specimen 0DEV4D from CCDI case PBBRHB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 14.4 years (5,261 days).
Specimen 0DEV4D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30e61cbf-158a-4607-bd9a-05b4f91d5824.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEV2E (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88a770e0-46d5-47ec-a820-b72e1925aa10

The open-access MAF lists 17 somatic variants for this specimen: 8 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 7, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP65 | c.3556G>A p.V1186M | Missense Mutation (SNP) | VAF 250/1127 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs766698692, COSV58564485; called by muse, mutect2, varscan2
- FASTKD1 | c.2431C>T p.R811C | Missense Mutation (SNP) | VAF 88/930 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs753928365; called by muse, mutect2
- GFRA2 | c.1142C>T p.T381M | Missense Mutation (SNP) | VAF 117/602 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs375798460, COSV60778678; called by muse, mutect2, varscan2
- PKP2 | c.635G>C p.R212P | Missense Mutation (SNP) | VAF 99/502 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.769); catalogued as COSV99298016; called by muse, mutect2, varscan2
- FLNC | c.2256C>A p.S752R | Missense Mutation (SNP) | VAF 64/854 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PANX3 | c.757A>T p.T253S | Missense Mutation (SNP) | VAF 66/718 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0.024); called by muse, mutect2
- SLC8A1 | c.1360G>T p.G454W | Missense Mutation (SNP) | VAF 135/664 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TIGD6 | c.111T>A p.F37L | Missense Mutation (SNP) | VAF 140/764 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- CARS1 | c.1089C>T p.H363= | Silent (SNP) | VAF 87/990 reads (9%) | catalogued as rs760604996; called by muse, mutect2
- MUC2 | c.2829C>G p.P943= | Silent (SNP) | VAF 109/409 reads (27%) | called by muse, mutect2, varscan2
- MUC5B | c.13458G>A p.T4486= | Silent (SNP) | VAF 27/252 reads (11%) | catalogued as rs746678966, COSV71594273; called by muse, mutect2, varscan2
- MYO15A | c.7938A>G p.A2646= | Silent (SNP) | VAF 94/473 reads (20%) | catalogued as rs1445365808; called by muse, mutect2, varscan2
- PCDHB7 | c.1671C>T p.N557= | Silent (SNP) | VAF 22/228 reads (10%) | called by muse, mutect2
- RBM20 | c.1308C>T p.H436= | Silent (SNP) | VAF 89/587 reads (15%) | catalogued as rs189600634; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCNN1G | c.906C>T p.S302= | Silent (SNP) | VAF 58/766 reads (8%) | catalogued as rs377135532; called by muse, mutect2
- E2F7 | c.*62G>A | 3'UTR (SNP) | VAF 26/112 reads (23%) | called by muse, mutect2, varscan2
- PPIE | c.31+62G>T | Intron (SNP) | VAF 31/203 reads (15%) | called by muse, mutect2, varscan2
